Somatic mutation profile of tumor specimen TCGA-55-8506-01A (aliquot TCGA-55-8506-01A-11D-2393-08) from TCGA case TCGA-55-8506, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.6 years (22,850 days).
Specimen TCGA-55-8506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cfdf0dc-e83a-4001-87d6-89d570936fcc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8506-10A (Blood Derived Normal), aliquot TCGA-55-8506-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad708c2d-e1b7-4e08-be32-b71c26310c41

The open-access MAF lists 1,922 somatic variants for this specimen: 1,472 protein-altering or splice-affecting, 409 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,171, Silent 409, Frame Shift Del 109, Nonsense Mutation 87, Frame Shift Ins 37, Splice Site 36, Intron 17, RNA 14, Splice Region 14, In Frame Del 12, 5'Flank 5, Translation Start Site 5.

Variants (750 of 1,922; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs113994128, CM011271, COSV99648335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BEST1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372989281, CM100163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 68/144 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- FANCA | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755546887, CM050609, COSV59795674; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.477dup p.E160Rfs*10 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- GAA | c.2242dup p.E748Gfs*48 | Frame Shift Ins (INS) | VAF 12/96 reads (13%) | catalogued as rs777275355; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- AASDH | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220618; called by muse, mutect2, varscan2
- ABCA13 | c.8865G>T p.L2955F | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); catalogued as COSV101446717; called by muse, varscan2
- ABCA5 | c.4495G>C p.V1499L | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV101200931; called by muse, mutect2, varscan2
- ABCB5 | c.3247G>T p.E1083* (on ENST00000404938 / NM_001163941.2; = p.E638* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 30/85 reads (35%) | catalogued as rs1333814179, COSV51704169; called by muse, mutect2, varscan2
- ACADVL | c.1211T>A p.M404K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99138279; called by muse, mutect2, varscan2
- ACCS | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99772622; called by muse, mutect2, varscan2
- ACE2 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); catalogued as COSV99382491; called by muse, mutect2, varscan2
- ACER1 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100033906; called by muse, mutect2, varscan2
- ACR | c.711G>A p.Q237= | Splice Region (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99334303, COSV99334490; called by muse, mutect2, varscan2
- ACTN2 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100856482; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 28/111 reads (25%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1671C>A p.D557E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99975888; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS16 | c.1050A>G p.P350= | Splice Region (SNP) | VAF 40/221 reads (18%) | catalogued as rs756897056, COSV99939716; called by muse, mutect2, varscan2
- ADAMTS17 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99170317; called by muse, mutect2, varscan2
- ADAMTS2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV99200993; called by muse, mutect2, varscan2
- ADAMTS4 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs376460245, COSV100917297; called by muse, mutect2, varscan2
- ADAMTS9 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55791772; called by muse, mutect2, varscan2
- ADAMTSL1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99440572; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs143798746; called by muse, mutect2, varscan2
- ADCY10 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100896512; called by muse, mutect2, varscan2
- ADCY2 | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV100601511; called by muse, mutect2
- ADGRB1 | c.2984A>G p.N995S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1563736599, COSV100029079; called by muse, mutect2, varscan2
- ADGRG2 | c.2275G>T p.D759Y (on ENST00000379869 / NM_001079858.3; = p.D756Y on NM_005756.4) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100491799, COSV61338680; called by muse, mutect2, varscan2
- ADGRG4 | c.6352A>T p.R2118W | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV99794156; called by muse, mutect2, varscan2
- ADGRG6 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs753293070, COSV51588750; called by muse, mutect2, varscan2
- ADNP2 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100080479; called by muse, mutect2, varscan2
- ADORA1 | c.529A>G p.M177V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1439358143, COSV99704318; called by mutect2, varscan2
- ADRA1D | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.092); catalogued as COSV65240319, COSV65241802; called by muse, mutect2, varscan2
- AFAP1 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.488); catalogued as COSV100631057; called by muse, mutect2, varscan2
- AGBL1 | c.2043G>T p.W681C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101222067; called by muse, mutect2, varscan2
- AGT | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100794182; called by muse, mutect2, varscan2
- AHDC1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99898779; called by muse, mutect2, varscan2
- AHNAK | c.9410C>T p.P3137L | Missense Mutation (SNP) | VAF 226/466 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99945269; called by muse, mutect2, varscan2
- AHNAK2 | c.10368G>T p.E3456D | Missense Mutation (SNP) | VAF 170/440 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV100315173; called by muse, mutect2, varscan2
- AIFM1 | c.1814C>A p.A605D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99780688; called by muse, mutect2, varscan2
- AIFM3 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100104086; called by muse, mutect2, varscan2
- AIM2 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.304); catalogued as rs371460238, COSV99058684; called by muse, mutect2, varscan2
- AKAP9 | c.7880C>G p.A2627G (on ENST00000359028; = p.A2603G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.437); catalogued as COSV100661833, COSV62360520; called by muse, mutect2, varscan2
- AL117348.2 | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | PolyPhen benign (0.02); catalogued as rs776969751, COSV99686413; called by muse, mutect2, varscan2
- AL592490.1 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.866); catalogued as rs147088518; called by muse, mutect2, varscan2
- ALMS1 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV100040900; called by muse, mutect2, varscan2
- ALMS1 | c.3841G>T p.V1281L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV100040903; called by muse, mutect2, varscan2
- ALPK1 | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99452890; called by muse, mutect2, varscan2
- AMDHD2 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99565548; called by muse, mutect2
- AMER1 | c.2699A>T p.E900V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100365168; called by muse, mutect2, varscan2
- AMER1 | c.2025G>T p.Q675H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV57672045; called by muse, mutect2, varscan2
- AMER2 | c.1936G>T p.V646F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100766107, COSV100766353; called by muse, mutect2, varscan2
- AMFR | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs754922563, COSV51923585; called by muse, mutect2, varscan2
- AMPH | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57746518; called by muse, mutect2, varscan2
- ANGEL1 | c.1853-1G>T p.X618_splice | Splice Site (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99200295; called by muse, mutect2
- ANKRD44 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99983853; called by muse, mutect2, varscan2
- ANO4 | c.623G>T p.R208M (on ENST00000392977 / NM_001286615.2; = p.R173M on NM_178826.4) | Missense Mutation (SNP) | VAF 166/497 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.547); catalogued as rs755195189, COSV100151609; called by muse, mutect2, varscan2
- ANO5 | c.2558T>A p.M853K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61082233; called by muse, mutect2, varscan2
- ANO9 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs757068080, COSV100240724; called by muse, mutect2, varscan2
- AOX1 | c.2470G>C p.A824P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101021635; called by muse, mutect2, varscan2
- APBA1 | c.1849A>G p.R617G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs951156535, COSV55234629; called by muse, mutect2, varscan2
- APEX2 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100237887; called by muse, mutect2, varscan2
- APOA5 | c.901del p.R301Afs*37 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | catalogued as COSV57062830; called by mutect2, pindel, varscan2
- APOB | c.10503G>T p.K3501N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.913); catalogued as COSV51929005; called by muse, mutect2, varscan2
- APOB | c.6367A>T p.N2123Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99263163; called by muse, mutect2, varscan2
- APPBP2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs760914598, COSV99319389; called by muse, mutect2, varscan2
- AQP9 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99582529; called by muse, mutect2, varscan2
- ARGFX | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100544051; called by muse, mutect2, varscan2
- ARHGEF11 | c.3232G>T p.V1078L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100168158; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV63437785; called by muse, mutect2, varscan2
- ARRDC4 | c.389C>G p.S130W | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99164300; called by muse, mutect2, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel
- ASAP3 | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100369137; called by muse, mutect2, varscan2
- ASB16 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV99518719; called by muse, mutect2, varscan2
- ASB9 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV100995361; called by muse, mutect2, varscan2
- ASCL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57152675; called by muse, mutect2, varscan2
- ASH1L | c.7619G>A p.R2540Q (on ENST00000368346 / NM_001366177.2; = p.R2535Q on NM_018489.3) | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776090224, COSV64209384; called by muse, mutect2, varscan2
- ASH1L | c.2535G>T p.R845S | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.158); catalogued as COSV100853058; called by muse, mutect2, varscan2
- ASTE1 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV99393602; called by muse, mutect2, varscan2
- ASTN1 | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV99920169; called by muse, mutect2
- ASXL3 | c.3686T>A p.M1229K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV99322976; called by muse, mutect2, varscan2
- ATG2B | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100737636; called by muse, mutect2, varscan2
- ATP12A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs752166372, COSV99516848; called by muse, mutect2, varscan2
- ATP13A2 | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV100453848; called by muse, mutect2, varscan2
- ATP1A2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63402212; called by muse, mutect2, varscan2
- ATP2A1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs182391081, COSV100837047; called by muse, mutect2, varscan2
- ATP4A | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV99382021; called by muse, mutect2, varscan2
- ATP6V1A | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99849763; called by muse, mutect2, varscan2
- ATP6V1A | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849764; called by muse, mutect2, varscan2
- ATP6V1F | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs776935044, COSV99925739; called by muse, mutect2, varscan2
- ATP7A | c.2948C>T p.T983M | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs782094358, COSV100430140; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP8B2 | c.272A>T p.N91I (on ENST00000672630; = p.N58I on NM_001005855.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100527586; called by muse, mutect2, varscan2
- ATP8B3 | c.3546C>A p.S1182R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV100033911; called by muse, mutect2, varscan2
- ATRN | c.1962A>C p.E654D | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99496424; called by muse, mutect2, varscan2
- ATRNL1 | c.2291C>A p.S764Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100743833; called by muse, mutect2, varscan2
- ATRX | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100969881; called by muse, mutect2, varscan2
- ATXN2 | c.1769C>T p.S590L (on ENST00000550104; = p.S430L on NM_002973.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs201658919, COSV66484680; called by muse, mutect2, varscan2
- ATXN3 | c.917_918insA p.D307Gfs*11 | Frame Shift Ins (INS) | VAF 5/81 reads (6%) | catalogued as COSV61493521, COSV61496159; called by muse*, mutect2, varscan2*
- AXDND1 | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100858231; called by muse, mutect2, varscan2
- B3GNT4 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99927979; called by muse, mutect2, varscan2
- B3GNT7 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99805811; called by muse, mutect2, varscan2
- BABAM2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs373361156; called by muse, mutect2, varscan2
- BAP1 | c.1890+2T>C p.X630_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99963284; called by muse, mutect2, varscan2
- BARD1 | c.1139del p.N380Tfs*20 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as COSV53618150; called by mutect2, pindel
- BAZ1A | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100701079; called by muse, mutect2, varscan2
- BAZ1B | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100289507; called by muse, mutect2, varscan2
- BBOX1 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99589384; called by muse, mutect2, varscan2
- BCHE | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100011970; called by muse, mutect2, varscan2
- BCORL1 | c.3007C>A p.L1003M | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99498248; called by muse, mutect2, varscan2
- BCORL1 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99498249; called by muse, mutect2, varscan2
- BEND4 | c.763A>T p.N255Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV101549704; called by muse, mutect2, varscan2
- BHLHE23 | c.329G>A p.R110Q (on ENST00000370346; = p.R126Q on NM_080606.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64846602; called by muse, mutect2
- BHMT2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV99669876; called by muse, mutect2, varscan2
- BICC1 | c.2909T>A p.V970D | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs373110130; called by muse, mutect2, varscan2
- BICD1 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861905; called by muse, mutect2, varscan2
- BICD1 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.629); catalogued as COSV99861906; called by muse, mutect2, varscan2
- BICRAL | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017711; called by muse, mutect2, varscan2
- BLOC1S4 | c.575A>C p.Q192P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100296591, COSV100296656; called by muse, mutect2, varscan2
- BPI | c.212G>T p.S71I (on ENST00000262865; = p.S67I on NM_001725.3) | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV99480341; called by muse, mutect2, varscan2
- BRAF | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV99949417; called by muse, mutect2, varscan2
- BRF2 | c.1001_1003del p.G334del | In Frame Del (DEL) | VAF 7/45 reads (16%) | catalogued as rs1460228573; called by mutect2, pindel, varscan2
- BRI3BP | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100412939; called by muse, mutect2, varscan2
- BRWD3 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100955584; called by muse, mutect2, varscan2
- BSX | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100545108; called by muse, varscan2
- C10orf71 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.447); catalogued as COSV100109577; called by muse, mutect2, varscan2
- C11orf16 | c.529T>G p.L177V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV100393582; called by muse, mutect2, varscan2
- C16orf90 | c.437C>A p.S146Y (on ENST00000399645 / NM_001353385.2; = p.S137Y on NM_001080524.2) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV101290949; called by muse, mutect2, varscan2
- C1orf116 | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100847857, COSV63944046; called by muse, mutect2, varscan2
- C1orf174 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.058); catalogued as COSV100851687; called by muse, mutect2, varscan2
- C1orf50 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.061); catalogued as COSV99354738; called by muse, mutect2, varscan2
- C2CD5 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100448397; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 21/156 reads (13%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C6 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666332; called by muse, mutect2, varscan2
- C6orf15 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV52539515, COSV99456579; called by muse, mutect2, varscan2
- CA10 | c.274A>T p.R92W | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99561212; called by muse, mutect2, varscan2
- CA9 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.443); catalogued as COSV100999756; called by muse, mutect2, varscan2
- CACNA1A | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs369134549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100214586; called by muse, mutect2, varscan2
- CACNA1D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs533046755, COSV55456930, COSV55467087; called by muse, mutect2, varscan2
- CACNA1E | c.5744C>T p.A1915V | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as COSV100701215, COSV62388275; called by muse, mutect2, varscan2
- CACNA2D1 | c.2302C>A p.L768I (on ENST00000356253 / NM_001366867.1; = p.L756I on NM_000722.4) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100665470; called by muse, mutect2, varscan2
- CACNA2D1 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV62390949; called by muse, mutect2, varscan2
- CACNG1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561976556, COSV99871580, COSV99871771; called by muse, mutect2
- CAD | c.6575+2T>A p.X2192_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99254292; called by muse, mutect2, varscan2
- CALCA | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs781865604, COSV100523876; called by muse, mutect2, varscan2
- CALHM1 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV99588215; called by muse, mutect2
- CALHM1 | c.244T>A p.W82R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV100324085; called by muse, mutect2, varscan2
- CAMKV | c.1163C>A p.P388Q | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV99614968; called by muse, mutect2, varscan2
- CAMSAP3 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV99349654; called by muse, mutect2, varscan2
- CAPN15 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757334558, COSV99562104; called by muse, mutect2, varscan2
- CAPN7 | c.1196C>G p.A399G | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99512517; called by muse, mutect2, varscan2
- CARD14 | c.910C>A p.R304S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100712469, COSV60127474; called by muse, mutect2, varscan2
- CARS1 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs376634473; called by muse, mutect2, varscan2
- CASK | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100586779; called by muse, mutect2
- CASKIN2 | c.1662G>A p.W554* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100050034; called by muse, mutect2, varscan2
- CC2D1A | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs769189689, COSV100528186; called by muse, mutect2, varscan2
- CCDC106 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 48/165 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs757718076, COSV99553010; called by muse, mutect2, varscan2
- CCDC120 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs782700988, COSV64481796; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC58 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as rs1262497292, COSV99216245; called by muse, mutect2, varscan2
- CCDC92 | c.65A>G p.N22S | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.124); catalogued as COSV99435111; called by muse, mutect2, varscan2
- CCL1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs150891376; called by muse, mutect2, varscan2
- CCL2 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV99861479; called by muse, mutect2, varscan2
- CCN4 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs745595165, COSV99136929, COSV99137063; called by muse, mutect2, varscan2
- CCR1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as rs200629341, COSV99946615; called by muse, mutect2, varscan2
- CD163 | c.2026C>G p.Q676E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs745589563, COSV100775590; called by muse, mutect2, varscan2
- CD22 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); catalogued as COSV99322746; called by muse, mutect2, varscan2
- CD300LD | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV100943877; called by muse, mutect2
- CDH10 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 47/129 reads (36%) | catalogued as rs964405219, COSV100049783; called by muse, mutect2, varscan2
- CDH12 | c.2026G>T p.G676W | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101200819; called by muse, mutect2, varscan2
- CDH12 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV66405981, COSV66444693; called by muse, mutect2
- CDH13 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as rs377383586, COSV99221541; called by muse, mutect2, varscan2
- CDH2 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV99295343; called by muse, mutect2, varscan2
- CDH23 | c.5509G>T p.V1837L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV99818451; called by muse, varscan2
- CDHR1 | c.248T>A p.V83D | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100258266; called by muse, mutect2, varscan2
- CDK9 | c.600G>T p.L200F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100953583; called by muse, mutect2, varscan2
- CEACAM5 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV99703701; called by muse, mutect2, varscan2
- CEACAM5 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99703702; called by muse, mutect2, varscan2
- CELA3A | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266345; called by muse, mutect2, varscan2
- CELSR1 | c.4037G>A p.G1346D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99416470; called by muse, mutect2, varscan2
- CELSR3 | c.3561C>A p.F1187L | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99372334, COSV99375414; called by muse, mutect2, varscan2
- CEP164 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV54043830, COSV99632402; called by muse, mutect2
- CEP170B | c.2987C>T p.P996L (on ENST00000453495; = p.P925L on NM_015005.3) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs373595600, COSV101371372; called by muse, mutect2, varscan2
- CEP170B | c.3091G>A p.A1031T (on ENST00000453495; = p.A960T on NM_015005.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV101371373; called by muse, mutect2, varscan2
- CFAP54 | c.5300C>A p.A1767D | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100732873; called by muse, mutect2, varscan2
- CFAP65 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838211; called by muse, mutect2, varscan2
- CFAP92 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99414534; called by muse, mutect2, varscan2
- CFH | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100808617; called by muse, mutect2, varscan2
- CGN | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV99641780; called by muse, mutect2, varscan2
- CHD8 | c.988G>T p.A330S (on ENST00000646647 / NM_001170629.2; = p.A51S on NM_020920.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV101303020; called by muse, mutect2, varscan2
- CHD8 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV101303023; called by muse, mutect2, varscan2
- CHRDL1 | c.520+1G>T p.X174_splice (on ENST00000372045; = p.X180_splice on NM_145234.4) | Splice Site (SNP) | VAF 21/130 reads (16%) | catalogued as COSV99487629; called by muse, mutect2, varscan2
- CHRNA2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs960814491, COSV99531834; called by muse, mutect2, varscan2
- CHRNB2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs796052326, COSV100872517; ClinVar: uncertain significance; called by muse, mutect2
- CHST2 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100535816; called by muse, mutect2, varscan2
- CLCN1 | c.2380G>T p.V794L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as CX1210498, COSV100577624; called by muse, mutect2, varscan2
- CLCN7 | c.1823T>G p.L608R | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99246816; called by muse, mutect2, varscan2
- CLEC17A | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100355002; called by muse, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs760557093; called by mutect2, varscan2
- CLEC4F | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99713478; called by muse, mutect2, varscan2
- CLEC5A | c.105C>G p.N35K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV101407739, COSV69397589; called by muse, varscan2
- CLEC9A | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100872679, COSV63351474; called by muse, mutect2, varscan2
- CLIP1 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211081; called by muse, mutect2, varscan2
- CLIP2 | c.120A>T p.E40D | Missense Mutation (SNP) | VAF 103/216 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as rs1554729322, COSV99790879; called by muse, mutect2, varscan2
- CLIP3 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as rs1175347230, COSV62112575; called by muse, mutect2, varscan2
- CLNK | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as COSV99904443; called by muse, mutect2, varscan2
- CMTR2 | c.1582G>T p.G528* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100578949, COSV100579382; called by muse, mutect2, varscan2
- CNBD1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV72917313; called by muse, mutect2
- CNKSR2 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV99667140; called by muse, mutect2, varscan2
- CNOT4 | c.1325A>C p.H442P (on ENST00000315544 / NM_001190848.1; = p.H439P on NM_013316.4) | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100210998; called by muse, mutect2, varscan2
- CNOT6 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV99993364; called by muse, mutect2, varscan2
- CNOT6 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99993365; called by muse, mutect2, varscan2
- CNOT9 | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99813592; called by muse, mutect2
- CNTN5 | c.1124G>C p.R375P | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296233, COSV99671964; called by muse, mutect2, varscan2
- CNTNAP5 | c.3351C>G p.D1117E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101442929, COSV101443132; called by muse, mutect2, varscan2
- COL11A1 | c.3454C>A p.P1152T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100614673; called by muse, mutect2, varscan2
- COL14A1 | c.4703C>G p.P1568R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99917696, COSV99919659; called by muse, mutect2, varscan2
- COL17A1 | c.2882C>A p.P961H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100792996; called by muse, mutect2, varscan2
- COL21A1 | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99777119; called by muse, mutect2, varscan2
- COL22A1 | c.4223G>T p.G1408V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275797; called by muse, mutect2, varscan2
- COL22A1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100275801; called by muse, mutect2, varscan2
- COL2A1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100475244, COSV61535374; called by muse, mutect2, varscan2
- COL4A2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100847131; called by muse, mutect2, varscan2
- COL4A2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64633650; called by muse, mutect2, varscan2
- COL4A5 | c.3112C>A p.Q1038K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.171); catalogued as COSV100086257; called by muse, mutect2, varscan2
- COL5A3 | c.3124C>A p.R1042= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99318098; called by muse, mutect2, varscan2
- COL7A1 | c.5772+2T>A p.X1924_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100094794; called by muse, mutect2
- COMMD4 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143103; called by muse, mutect2, varscan2
- COP1 | c.1678T>C p.C560R | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100442577; called by muse, mutect2, varscan2
- COP1 | c.1551G>T p.W517C | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442578; called by muse, mutect2, varscan2
- COTL1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749367597, COSV52289491, COSV52290276; called by muse, mutect2, varscan2
- CPEB1 | c.425C>G p.A142G (on ENST00000617958; = p.A82G on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV99917351; called by muse, mutect2, varscan2
- CPNE4 | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV101456551; called by muse, mutect2, varscan2
- CPSF1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568713664, COSV62939139; called by muse, mutect2, varscan2
- CRABP1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as rs778328549, COSV55116419; called by muse, mutect2, varscan2
- CRACDL | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1191309964, COSV101193934; called by muse, mutect2, varscan2
- CRB1 | c.2420T>C p.L807P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100957617; called by muse, mutect2, varscan2
- CREBZF | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.217); catalogued as COSV99476083; called by muse, mutect2, varscan2
- CRMP1 | c.1515G>C p.E505D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100271228; called by muse, mutect2, varscan2
- CRNKL1 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99842955; called by muse, mutect2, varscan2
- CROCC | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100978025; called by muse, mutect2, varscan2
- CROCC | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100978026; called by muse, mutect2, varscan2
- CROCC | c.2574G>C p.Q858H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100978027, COSV65011719; called by mutect2, varscan2
- CRP | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 307/523 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99660387; called by muse, mutect2, varscan2
- CRTAM | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV99911709; called by muse, mutect2, varscan2
- CRYGS | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100329884; called by muse, mutect2, varscan2
- CSF1R | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640677; called by muse, mutect2, varscan2
- CSF2RB | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as COSV99453161; called by muse, mutect2, varscan2
- CSF2RB | c.2378T>A p.V793D | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV99453163; called by muse, mutect2, varscan2
- CSHL1 | c.388A>T p.N130Y (on ENST00000309894 / NM_022581.3; = p.N36Y on NM_001318.4) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99367746; called by muse, mutect2
- CSMD1 | c.8674C>A p.L2892I (on ENST00000520002; = p.L2891I on NM_033225.6) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100142312; called by muse, mutect2, varscan2
- CSMD1 | c.2948A>C p.D983A (on ENST00000520002; = p.D982A on NM_033225.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100142316; called by muse, mutect2, varscan2
- CSPG4 | c.3539C>T p.A1180V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs371573067; called by muse, mutect2, varscan2
- CSPG4 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57890009; called by muse, mutect2
- CSRNP3 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.348); catalogued as COSV100084955; called by muse, mutect2, varscan2
- CUX2 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs373425760, COSV55641948; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYLC1 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100253939; called by muse, mutect2
- CYP2A13 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs771991041, COSV100387021, COSV57840255; called by muse, mutect2, varscan2
- CYP2A13 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs577832324, COSV57838786; called by muse, mutect2, varscan2
- CYP3A4 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100315375; called by muse, mutect2, varscan2
- CYP4F8 | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.158); catalogued as COSV100357979; called by muse, mutect2, varscan2
- CYYR1 | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV100176410; called by muse, mutect2, varscan2
- DAB1 | c.1029C>A p.F343L (on ENST00000371231; = p.F310L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV100976119; called by muse, mutect2, varscan2
- DACT1 | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1369994515, COSV60021323; called by muse, varscan2
- DAPK3 | c.783-1G>C p.X261_splice | Splice Site (SNP) | VAF 72/275 reads (26%) | catalogued as COSV100009431; called by muse, mutect2, varscan2
- DCAF13 | c.1080G>T p.L360F | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99884935; called by muse, mutect2, varscan2
- DCAF4L2 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100150421; called by muse, mutect2, varscan2
- DCHS1 | c.4757C>A p.S1586Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100201359, COSV55041666; called by muse, mutect2
- DCP1A | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV99587756; called by muse, mutect2, varscan2
- DCST1 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as rs958801714, COSV55062127; called by muse, mutect2
- DCTN5 | c.27_29del p.N9del | In Frame Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs779696050; called by pindel, varscan2
- DDB1 | c.2165+1G>C p.X722_splice | Splice Site (SNP) | VAF 60/212 reads (28%) | catalogued as COSV100074181; called by muse, mutect2, varscan2
- DDHD2 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101240464; called by muse, mutect2, varscan2
- DDI1 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56379123; called by muse, mutect2, varscan2
- DDIT4 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100259036; called by muse, mutect2, varscan2
- DDX1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.956); catalogued as rs753361392, COSV51838167; called by muse, mutect2, varscan2
- DDX10 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1335887851, COSV59434266; called by muse, mutect2, varscan2
- DDX39B | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871023, COSV100871070; called by muse, mutect2
- DEFB112 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.503); catalogued as COSV100452083, COSV59182560; called by muse, mutect2, varscan2
- DENND1C | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs375160320; called by muse, mutect2, varscan2
- DENND4B | c.304del p.L102Sfs*197 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs747842790; called by mutect2, pindel, varscan2
- DENND5A | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200941937, COSV100063899; called by muse, mutect2, varscan2
- DGKH | c.2051G>C p.R684P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99818155, COSV99818455; called by muse, mutect2, varscan2
- DGKK | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101052858; called by muse, mutect2, varscan2
- DIO2 | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101375806; called by muse, mutect2, varscan2
- DIP2B | c.2048+1G>T p.X683_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56578556, COSV99997761; called by muse, mutect2
- DIP2C | c.2713G>T p.G905C | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99789710; called by muse, mutect2, varscan2
- DISP3 | c.2614G>C p.V872L | Missense Mutation (SNP) | VAF 100/352 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV99607128; called by muse, mutect2, varscan2
- DIXDC1 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.195); catalogued as COSV100180031, COSV59460966; called by muse, mutect2, varscan2
- DKC1 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101059855; called by muse, mutect2, varscan2
- DKK2 | c.89G>C p.S30T | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99568035; called by muse, mutect2, varscan2
- DLAT | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99734367; called by muse, mutect2
- DLC1 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.025); catalogued as COSV99360494; called by muse, mutect2, varscan2
- DLG2 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV99712113; called by muse, mutect2, varscan2
- DLG2 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99712119; called by muse, mutect2, varscan2
- DLG5 | c.4226A>T p.Q1409L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.39); catalogued as COSV100967198; called by muse, mutect2, varscan2
- DLG5 | c.2380A>T p.K794* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100967199; called by muse, mutect2, varscan2
- DMD | c.7640G>C p.R2547T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1016099168, COSV100625673; called by muse, mutect2, varscan2
- DMP1 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs773197665, COSV99218438; called by muse, mutect2, varscan2
- DNAH11 | c.12610C>T p.P4204S | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176464; called by muse, mutect2, varscan2
- DNAH17 | c.3410C>T p.A1137V | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs750606968, COSV101101215; called by muse, mutect2, varscan2
- DNAH3 | c.7152G>T p.Q2384H | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99764551; called by muse, mutect2, varscan2
- DNAH6 | c.2424G>T p.L808F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52886717, COSV99404340; called by muse, mutect2
- DNAI2 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100209530, COSV56757935; called by muse, mutect2, varscan2
- DOCK2 | c.3695T>A p.L1232Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99909771; called by muse, mutect2, varscan2
- DOCK7 | c.5635G>T p.G1879* (on ENST00000635253 / NM_001367561.1; = p.G1848* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99222390; called by muse, mutect2, varscan2
- DOCK7 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99222391; called by muse, mutect2, varscan2
- DPP3 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100855389; called by muse, mutect2, varscan2
- DPPA3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV100559802; called by muse, mutect2, varscan2
- DPT | c.406A>T p.S136C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100892083; called by muse, mutect2
- DPYSL4 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100633794; called by muse, mutect2, varscan2
- DRD1 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101192357; called by muse, mutect2, varscan2
- DSCAM | c.5822C>T p.T1941M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.23); catalogued as rs780214745, COSV68040142; called by muse, mutect2, varscan2
- DSG3 | c.2195G>T p.G732V | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.558); catalogued as COSV99933659; called by muse, mutect2, varscan2
- DSG4 | c.2749T>A p.C917S | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100355199; called by muse, mutect2, varscan2
- DST | c.21169C>T p.L7057F (on ENST00000361203 / NM_001374722.1; = p.L4754F on NM_015548.5) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751937573, COSV99750037; called by muse, mutect2, varscan2
- DTNA | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52007223, COSV99310479; called by muse, mutect2, varscan2
- DUSP12 | c.861+1G>A p.X287_splice | Splice Site (SNP) | VAF 13/167 reads (8%) | catalogued as COSV100909661; called by muse, mutect2
- DUSP19 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.844); catalogued as rs369033410; called by muse, mutect2, varscan2
- DVL2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs761312377, COSV99138281; called by muse, mutect2, varscan2
- DVL2 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV50039980, COSV99138283; called by muse, mutect2, varscan2
- DVL3 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV99490238; called by muse, mutect2, varscan2
- DZIP3 | c.2832T>A p.S944R | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV100847567; called by muse, mutect2, varscan2
- ECD | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100881325; called by muse, mutect2, varscan2
- EDEM3 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100544804; called by muse, mutect2
- EEF1AKNMT | c.842G>T p.R281L (on ENST00000361735 / NM_015935.5; = p.R195L on NM_014955.3) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100675745; called by muse, mutect2, varscan2
- EEF2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100500532; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs373416028; called by muse, mutect2, varscan2
- ELAPOR2 | c.2453A>G p.Y818C (on ENST00000450689 / NM_001142749.3; = p.Y651C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99788042; called by muse, mutect2, varscan2
- ELAPOR2 | c.1700G>C p.W567S (on ENST00000450689 / NM_001142749.3; = p.W400S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99788043; called by muse, mutect2, varscan2
- ELK1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99901822; called by muse, mutect2, varscan2
- ELMOD1 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753463613, COSV56195625, COSV99759586; called by muse, mutect2, varscan2
- ELOC | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV99513794; called by muse, mutect2, varscan2
- ELP5 | c.788_791del p.R263Kfs*6 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs774974229; called by mutect2, pindel, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 22/154 reads (14%) | catalogued as rs759858342; called by mutect2, varscan2
- EMSY | c.2089A>G p.R697G | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100595283; called by muse, mutect2, varscan2
- ENOX1 | c.1444C>A p.Q482K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.931); catalogued as COSV99814829; called by muse, mutect2, varscan2
- EP400 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as rs745405091, COSV100200197; called by muse, mutect2, varscan2
- EP400 | c.8101A>T p.T2701S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.946); catalogued as COSV100200199; called by muse, mutect2, varscan2
- EPAS1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320324950, COSV55386288; called by muse, mutect2, varscan2
- EPHA2 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775894984, COSV64453517; called by muse, mutect2
- EPHX1 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV55302000, COSV99688657; called by muse, mutect2, varscan2
- EPPK1 | c.5570C>T p.A1857V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1554659569, COSV101599717; called by muse, mutect2, varscan2
- ERBB4 | c.3725A>T p.Y1242F | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100722631, COSV61476936; called by muse, mutect2, varscan2
- ERCC6 | c.4385A>T p.Q1462L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV100875600; called by muse, mutect2, varscan2
- ERCC6 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs267602507, COSV100875601; called by muse, mutect2, varscan2
- ERCC6L2 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99998185; called by muse, mutect2, varscan2
- ERICH6 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99901286; called by muse, mutect2, varscan2
- ERN2 | c.1399del p.L467Wfs*48 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | catalogued as rs763540496, COSV99078581; called by mutect2, pindel, varscan2
- ERRFI1 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV101087926; called by muse, mutect2, varscan2
- ESAM | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99631524; called by muse, mutect2, varscan2
- ESR1 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV99237414; called by muse, mutect2, varscan2
- ESYT2 | c.886A>T p.I296F (on ENST00000613624; = p.I220F on NM_020728.3) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99275931; called by muse, mutect2
- ESYT2 | c.886-1G>T p.X296_splice (on ENST00000613624; = p.X220_splice on NM_020728.3) | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99275933; called by muse, mutect2
- EVC2 | c.2360G>C p.R787P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100184825; called by muse, mutect2, varscan2
- EXTL1 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100959037; called by muse, mutect2, varscan2
- F11 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99251098; called by muse, mutect2, varscan2
- F2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319286; called by muse, mutect2, varscan2
- F2RL2 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.925); catalogued as COSV56972596; called by muse, mutect2, varscan2
- FAAP24 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as COSV99576928; called by muse, mutect2, varscan2
- FAHD2B | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99737863; called by muse, mutect2, varscan2
- FAM110C | c.772A>G p.S258G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100566806; called by muse, mutect2, varscan2
- FAM124A | c.362G>A p.R121H (on ENST00000322475 / NM_001242312.2; = p.R157H on NM_145019.4) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as rs767125700, COSV54479551; called by muse, mutect2
- FAM131B | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100577625, COSV58367480; called by muse, mutect2, varscan2
- FAM135B | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV99417741; called by muse, mutect2, varscan2
- FAM13C | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99512919; called by muse, mutect2, varscan2
- FAM168A | c.511G>A p.V171I (on ENST00000064778 / NM_001286050.2; = p.V162I on NM_015159.3) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as rs1254760513, COSV50358968; called by muse, mutect2, varscan2
- FAM171A1 | c.987-2A>T p.X329_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100967952; called by muse, varscan2
- FAM186B | c.1978_1980del p.K660del | In Frame Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs777861400; called by pindel, varscan2
- FAM47A | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.045); catalogued as rs1279201108, COSV100649672, COSV60499173; called by muse, varscan2
- FAM47A | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs778243689, COSV60499323; called by muse, varscan2
- FAM47A | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV100649673, COSV60499408; called by muse, varscan2
- FAM53A | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs775759980, COSV100356790, COSV57401689; called by muse, mutect2, varscan2
- FAM71A | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as rs775317074, COSV54236719; called by muse, mutect2
- FAM71B | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV100261721; called by muse, mutect2, varscan2
- FAM71F2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV101100639; called by muse, mutect2, varscan2
- FAM83H | c.1477G>C p.A493P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101186910; called by muse, mutect2
- FAM83H | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041083111, COSV101186911; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FASN | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100147201; called by muse, mutect2
- FBLN7 | c.75+2T>C p.X25_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as rs1217247969, COSV100485406; called by muse, mutect2, varscan2
- FBN2 | c.3407G>A p.G1136D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99324346; called by muse, mutect2, varscan2
- FBN2 | c.2664G>T p.L888F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99324349, COSV99325964; called by muse, mutect2, varscan2
- FBN3 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs951781682, COSV99559493; called by muse, mutect2, varscan2
- FBXO27 | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 48/172 reads (28%) | catalogued as COSV99494465; called by muse, mutect2, varscan2
- FBXW10 | c.3085G>A p.G1029S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100111164; called by muse, mutect2, varscan2
- FBXW12 | c.1206C>A p.H402Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV56484945; called by muse, mutect2, varscan2
- FCER1A | c.14T>A p.M5K | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100929238; called by muse, mutect2, varscan2
- FCGRT | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99571120; called by muse, mutect2, varscan2
- FCHSD1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs544582821, COSV99781113; called by mutect2, varscan2
- FCN1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.099); catalogued as rs764414692, COSV100878802, COSV100878835; called by muse, mutect2, varscan2
- FCRL1 | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV100839699, COSV63823726; called by muse, mutect2, varscan2
- FCRL3 | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 101/180 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100942740; called by muse, mutect2, varscan2
- FER1L6 | c.4177C>T p.R1393W | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376465322; called by muse, mutect2, varscan2
- FEZ1 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV54026386, COSV99630172; called by muse, mutect2, varscan2
- FFAR2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.136); catalogued as COSV99875944; called by muse, mutect2, varscan2
- FGD3 | c.421del p.Q141Rfs*33 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1214182725; called by mutect2, pindel, varscan2
- FHOD3 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV99939835; called by muse, mutect2, varscan2
- FLNA | c.6088G>A p.V2030M (on ENST00000369850 / NM_001110556.2; = p.V2022M on NM_001456.3) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs781920955, COSV100774235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99607089; called by muse, mutect2, varscan2
- FMO1 | c.124A>T p.R42* | Nonsense Mutation (SNP) | VAF 40/204 reads (20%) | catalogued as COSV100707675; called by muse, mutect2, varscan2
- FOCAD | c.3748G>T p.D1250Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs756707091, COSV100619939; called by muse, mutect2, varscan2
- FOXB2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV65022521; called by muse, mutect2, varscan2
- FOXC2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV100234068, COSV57444966; called by muse, mutect2, varscan2
- FOXO4 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100446753; called by muse, mutect2, varscan2
- FRAS1 | c.10508C>A p.S3503Y | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53611552, COSV99347602; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMD4A | c.1816A>G p.I606V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100661043; called by muse, mutect2, varscan2
- FRMPD3 | c.2895C>A p.N965K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV99345474; called by muse, mutect2
- FRYL | c.4360T>C p.S1454P | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99975437; called by muse, mutect2, varscan2
- FSD2 | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100574982; called by muse, mutect2, varscan2
- GABRA4 | c.1145C>A p.A382D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as COSV99973355; called by muse, mutect2, varscan2
- GABRD | c.1171T>A p.Y391N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV101059500; called by muse, mutect2, varscan2
- GABRQ | c.480T>A p.N160K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs1471208213, COSV100941068; called by muse, mutect2, varscan2
- GAL3ST1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100142895; called by muse, mutect2, varscan2
- GALNT14 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV100203971; called by muse, mutect2, varscan2
- GALNT2 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100795371; called by muse, mutect2, varscan2
- GALNT2 | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795372; called by muse, mutect2
- GALP | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs139843226; called by muse, mutect2, varscan2
- GALR2 | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100134740; called by muse, mutect2
- GATA3 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650772; called by muse, mutect2, varscan2
- GBA | c.203dup p.T69Dfs*12 | Frame Shift Ins (INS) | VAF 10/81 reads (12%) | catalogued as rs1170895261; called by mutect2, pindel, varscan2
- GBF1 | c.4715C>T p.A1572V (on ENST00000369983 / NM_001377137.1; = p.A1571V on NM_004193.3) | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890270; called by muse, mutect2, varscan2
- GBP6 | c.675G>T p.R225S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100969443; called by muse, varscan2
- GCC1 | c.2116A>T p.I706F | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs771413693, COSV100365329; called by muse, mutect2, varscan2
- GDAP1 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1445467720, COSV55187639, COSV99619246; called by muse, varscan2
- GDF5 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1046039478, COSV100976703; called by muse, mutect2
- GDPD2 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.039); catalogued as COSV100978526; called by muse, mutect2
- GGT7 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.778); catalogued as COSV100321686; called by muse, mutect2, varscan2
- GGT7 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs371027305; called by muse, mutect2, varscan2
- GHSR | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99576635; called by muse, mutect2, varscan2
- GIGYF1 | c.1491G>T p.E497D | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99308654; called by muse, mutect2, varscan2
- GIMAP7 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100543537; called by muse, mutect2, varscan2
- GLIS2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV99267260; called by muse, mutect2, varscan2
- GLRA2 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99490079; called by muse, mutect2, varscan2
- GLRA2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs777077152, COSV54341910; called by muse, mutect2, varscan2
- GLT8D2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as rs181331226; called by muse, mutect2, varscan2
- GNAL | c.798C>A p.N266K (on ENST00000269162 / NM_001142339.3; = p.N343K on NM_182978.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99302937; called by muse, mutect2, varscan2
- GNAS | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as COSV100005064; called by muse, varscan2
- GNL1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs754395828, COSV100925386; called by muse, mutect2, varscan2
- GNL2 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV99953434; called by muse, mutect2, varscan2
- GOLGB1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762516224, COSV100510237; called by muse, mutect2, varscan2
- GON4L | c.6051G>T p.R2017S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV99673096; called by muse, mutect2, varscan2
- GPATCH1 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs1464997859, COSV50111125; called by muse, mutect2
- GPATCH3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV64652765; called by muse, mutect2, varscan2
- GPC4 | c.1635C>A p.C545* | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | catalogued as COSV100895345; called by muse, mutect2, varscan2
- GPKOW | c.1140+2T>A p.X380_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99332452; called by muse, mutect2
- GPR12 | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101197933; called by muse, mutect2, varscan2
- GPR132 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as rs558947453, COSV61677499; called by muse, mutect2, varscan2
- GPR139 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429580, COSV58504142; called by muse, mutect2, varscan2
- GPR158 | c.2731G>T p.E911* | Nonsense Mutation (SNP) | VAF 71/238 reads (30%) | catalogued as COSV66266670; called by muse, mutect2, varscan2
- GPR161 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV99606072; called by muse, mutect2, varscan2
- GPR174 | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52132690; called by muse, mutect2, varscan2
- GPR4 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.039); catalogued as COSV100546880; called by muse, mutect2, varscan2
- GRIN3A | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV100701323; called by muse, mutect2, varscan2
- GRM3 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.985); catalogued as COSV100862026, COSV64478495; called by muse, mutect2, varscan2
- GRM6 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99179427; called by muse, mutect2, varscan2
- GRM8 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100279908, COSV100283900; called by muse, mutect2, varscan2
- GSK3B | c.916C>T p.R306* (on ENST00000264235 / NM_001146156.2; = p.R319* on NM_002093.4) | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs768552900, COSV51774118; called by muse, mutect2, varscan2
- GSPT2 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100467875; called by muse, mutect2, varscan2
- GSTA1 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575410; called by muse, mutect2, varscan2
- GUCY1B1 | c.1690G>T p.V564L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV100025234; called by muse, mutect2, varscan2
- GUCY2C | c.160T>A p.L54M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99663140; called by muse, mutect2, varscan2
- H1-8 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100180339; called by muse, mutect2
- H2BC11 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100345561; called by muse, mutect2, varscan2
- H3-4 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV64210524; called by muse, mutect2
- HAUS6 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100997720; called by mutect2, varscan2
- HAVCR2 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100324580; called by muse, mutect2, varscan2
- HAVCR2 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV100324584; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 25/188 reads (13%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HBG2 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV57963186, COSV57964307; called by muse, mutect2, varscan2
- HCFC1 | c.4675C>A p.Q1559K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV100128282; called by muse, mutect2
- HCN3 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100855541; called by muse, mutect2, varscan2
- HCN4 | c.1612A>T p.M538L | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99983177; called by muse, mutect2, varscan2
- HDAC5 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52242030; called by muse, mutect2, varscan2
- HDAC7 | c.1089dup p.S364Qfs*33 (on ENST00000427332; = p.S403Qfs*33 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/87 reads (9%) | catalogued as rs750203996; called by mutect2, pindel
- HDGF | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100625569; called by muse, mutect2, varscan2
- HECW2 | c.2741C>T p.T914M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs375518920, COSV53679191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HELZ2 | c.6620G>T p.G2207V (on ENST00000467148 / NM_001037335.2; = p.G1638V on NM_033405.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV101427505; called by muse, varscan2
- HEPHL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as COSV100243373; called by muse, mutect2, varscan2
- HERC2 | c.11285A>T p.Q3762L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99870320; called by muse, mutect2, varscan2
- HERC2 | c.4496G>A p.G1499D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763287026, COSV99870323; called by muse, mutect2, varscan2
- HERC5 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs533028212, COSV99987320; called by muse, mutect2, varscan2
- HES3 | c.84C>A p.I28= | Splice Region (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100928434; called by muse, mutect2, varscan2
- HFM1 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV99645182; called by muse, mutect2, varscan2
- HIBADH | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV99606813; called by muse, mutect2, varscan2
- HK2 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1245632368, COSV99308434; called by muse, mutect2
- HMCN1 | c.15403G>A p.G5135S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99623086; called by muse, mutect2, varscan2
- HMGCS1 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100284889; called by muse, mutect2
- HMGXB4 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99329870; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs761272507; called by mutect2, varscan2
- HOATZ | c.65del p.G22Dfs*78 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | catalogued as COSV100239592; called by mutect2, pindel, varscan2
- HORMAD1 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777923537, COSV59270206; called by muse, mutect2, varscan2
- HOXA1 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.275); catalogued as COSV99760954; called by muse, mutect2, varscan2
- HOXA10 | c.957G>T p.L319= | Splice Region (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99385223; called by muse, mutect2, varscan2
- HOXA13 | c.667T>A p.S223T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV99763464; called by muse, mutect2, varscan2
- HOXA2 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56067878, COSV99760955; called by muse, mutect2, varscan2
- HOXA3 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100415263; called by muse, mutect2, varscan2
- HOXD13 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV66832973; called by muse, mutect2, varscan2
- HPGD | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640037; called by muse, mutect2, varscan2
- HPN | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99384783; called by muse, mutect2, varscan2
- HSPA12A | c.481A>T p.K161* | Nonsense Mutation (SNP) | VAF 52/175 reads (30%) | catalogued as COSV100979700; called by muse, mutect2, varscan2
- HSPA13 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99579819; called by muse, mutect2, varscan2
- HSPA2 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99904671; called by muse, mutect2, varscan2
- HTR1E | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100540870; called by muse, mutect2, varscan2
- ICAM5 | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs1240446166, COSV99703049; called by muse, mutect2, varscan2
- ICE2 | c.1161G>C p.E387D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.824); catalogued as COSV99831211; called by muse, mutect2, varscan2
- IFI44L | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100654841; called by muse, mutect2, varscan2
- IFNL1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100373612; called by muse, mutect2, varscan2
- IGDCC4 | c.3008C>G p.S1003C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100732628; called by muse, mutect2
- IGFL4 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1461575002, COSV100890813; called by muse, mutect2, varscan2
- IGFN1 | c.3361G>A p.G1121R (on ENST00000295591 / NM_001367841.1; = p.G3578R on NM_001164586.2) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810891; called by muse, mutect2, varscan2
- IGKV2D-29 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV101534351, COSV101534355; called by muse, mutect2, varscan2
- IGLV4-60 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV101135181; called by muse, mutect2, varscan2
- IGSF3 | c.1303C>T p.R435C (on ENST00000369486 / NM_001007237.3; = p.R455C on NM_001542.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs776912571, COSV100604041; called by muse, mutect2, varscan2
- IL10 | c.340del p.E114Rfs*3 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | catalogued as COSV65594492; called by mutect2, pindel, varscan2
- IL13RA2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs148209653, COSV99682817; called by muse, mutect2, varscan2
- ILDR2 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99613079; called by muse, mutect2, varscan2
- ILDR2 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV99613086; called by muse, mutect2, varscan2
- IMPG1 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV100885796, COSV64057430; called by muse, mutect2, varscan2
- INA | c.1191G>A p.R397= | Splice Region (SNP) | VAF 17/118 reads (14%) | catalogued as rs764506642, COSV100878552; called by muse, mutect2, varscan2
- INPP5E | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV51525915; called by muse, mutect2, varscan2
- INSC | c.524C>A p.S175Y | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.198); catalogued as COSV101088677; called by muse, mutect2, varscan2
- INSR | c.2311A>G p.T771A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV100251210; called by muse, mutect2, varscan2
- INSR | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV100251213, COSV57166599; called by muse, mutect2, varscan2
- INSRR | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100947049; called by muse, mutect2, varscan2
- INTS6L | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100878001, COSV66086702; called by muse, mutect2, varscan2
- IPO13 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV100961015; called by muse, mutect2, varscan2
- IPPK | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs1434419457, COSV55335448, COSV99845337; called by muse, mutect2, varscan2
- IRAG1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs371956442; called by muse, mutect2, varscan2
- IRF2BP2 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.401); catalogued as COSV100784222; called by muse, mutect2, varscan2
- IRF7 | c.1144C>T p.R382W (on ENST00000397566; = p.R369W on NM_001572.5) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs779495519, COSV99199367; called by muse, mutect2, varscan2
- IRGC | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV99745995; called by muse, mutect2, varscan2
- IRX1 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100116175; called by muse, mutect2
- IRX2 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100121544; called by muse, mutect2, varscan2
- ISLR | c.1173C>A p.S391R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV99997109; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV99860586; called by muse, mutect2, varscan2
- ITGA4 | c.2368G>T p.G790* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV101223038; called by muse, mutect2, varscan2
- ITGAD | c.3367T>C p.Y1123H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150458084; called by muse, mutect2
- ITGAM | c.1814G>T p.G605V (on ENST00000648685 / NM_001145808.2; = p.G604V on NM_000632.4) | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99791656; called by muse, mutect2, varscan2
- ITGAV | c.1925+2T>C p.X642_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99654123; called by muse, mutect2, varscan2
- ITGBL1 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | catalogued as COSV66010985; called by muse, varscan2
- ITGBL1 | c.1395G>T p.G465= | Splice Region (SNP) | VAF 65/178 reads (37%) | catalogued as COSV101084223; called by muse, mutect2, varscan2
- ITIH6 | c.2617A>T p.K873* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99512758; called by muse, varscan2
- ITPR3 | c.7018T>C p.F2340L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100966833; called by muse, mutect2, varscan2
- ITPRID1 | c.2114C>A p.S705Y | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100085488; called by muse, mutect2
- IWS1 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as COSV99766955; called by muse, mutect2, varscan2
- JAKMIP3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375429968; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- JPH4 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100436486; called by muse, mutect2, varscan2
- KANK4 | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100443071; called by muse, mutect2, varscan2
- KATNIP | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV55187559; called by muse, mutect2
- KCNA10 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377713297, COSV100871385; called by muse, mutect2, varscan2
- KCNA5 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs771138144, COSV99363541; called by muse, mutect2, varscan2
- KCNAB2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99378497; called by muse, mutect2, varscan2
- KCNE5 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100927690; called by muse, mutect2, varscan2
- KCNH3 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.33); catalogued as rs750500026, COSV99234619; called by muse, mutect2, varscan2
- KCNH5 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs758320399, COSV100526189, COSV59769497; called by muse, mutect2, varscan2
- KCNH5 | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100525069; called by muse, mutect2, varscan2
- KCNK2 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV67210832; called by muse, mutect2, varscan2
- KCNN1 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV99715568; called by muse, mutect2, varscan2
- KCNN4 | c.64_66del p.E22del | In Frame Del (DEL) | VAF 42/177 reads (24%) | catalogued as rs751361496; called by mutect2, pindel, varscan2
- KCNQ2 | c.2551C>A p.P851T (on ENST00000359125 / NM_172107.4; = p.P823T on NM_004518.6) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100609394; called by muse, mutect2, varscan2
- KCNQ4 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778109027, COSV100714261; called by muse, mutect2, varscan2
- KCNS1 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752243589, COSV100066978; called by muse, mutect2, varscan2
- KCNT2 | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99651016; called by muse, mutect2, varscan2
- KCNU1 | c.2481G>T p.L827F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs756100701, COSV101298767; called by muse, mutect2, varscan2
- KCNV2 | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV101172469; called by muse, mutect2, varscan2
- KCTD13 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV100441957; called by muse, mutect2, varscan2
- KDF1 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as COSV100264348; called by muse, mutect2, varscan2
- KDM4A | c.1616C>T p.T539M | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs192175863, COSV100969347; called by muse, mutect2, varscan2
- KEAP1 | c.1848G>T p.Q616H | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV99407219; called by muse, mutect2, varscan2
- KIAA1217 | c.3426G>T p.K1142N | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100286099; called by muse, mutect2, varscan2
- KIAA2026 | c.3270G>T p.M1090I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101198798; called by muse, mutect2, varscan2
- KIF1C | c.1936A>T p.R646W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100296917; called by muse, mutect2
- KIF1C | c.1937G>A p.R646K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as rs1394085981, COSV100296918; called by muse, mutect2
- KIF20A | c.1649A>C p.E550A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV101203065; called by muse, mutect2, varscan2
- KIR3DL2 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99551695; called by muse, mutect2, varscan2
- KIRREL1 | c.1171+2T>C p.X391_splice | Splice Site (SNP) | VAF 9/169 reads (5%) | catalogued as COSV100779182, COSV63286418; called by muse, mutect2
- KIRREL2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761189830, COSV52877346; called by muse, mutect2, varscan2
- KIRREL3 | c.1499C>A p.T500K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV101375163; called by muse, mutect2, varscan2
- KLF13 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100207031; called by muse, mutect2, varscan2
- KLF4 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867964623, COSV65928854; called by muse, mutect2
- KLHDC4 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54506372, COSV99565919; called by muse, mutect2, varscan2
- KLHL1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197296850, COSV100916875; called by muse, mutect2, varscan2
- KLHL25 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139035411; called by muse, mutect2, varscan2
- KLRD1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.383); catalogued as COSV100282102, COSV60272890; called by muse, mutect2, varscan2
- KMT2A | c.5963A>G p.E1988G | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100627738; called by muse, mutect2, varscan2
- KRBA1 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV99752116; called by muse, mutect2
- KRBA1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs763076723, COSV99752120; called by muse, mutect2, varscan2
- KRBOX4 | c.379A>T p.R127* (on ENST00000344302 / NM_001129898.2; = p.R122* on NM_017776.2) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99994155; called by muse, mutect2, varscan2
- KRT13 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764004897, COSV99877135; called by muse, mutect2, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs769596857; called by mutect2, varscan2
- KRT24 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV99231904; called by muse, mutect2
- KRT25 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100379772; called by muse, mutect2
- KRTAP1-5 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs199685389, COSV62624492; called by muse, mutect2, varscan2
- KRTAP10-12 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1555950905, COSV100551559; called by muse, varscan2
- KRTAP10-12 | c.537C>G p.C179W | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100551563; called by muse, varscan2
- KRTAP10-9 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59966841; called by muse, mutect2, varscan2
- KRTAP11-1 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100190461; called by muse, mutect2, varscan2
- KRTAP17-1 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | PolyPhen probably damaging (0.998); catalogued as COSV100498531; called by muse, mutect2, varscan2
- KRTAP19-6 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 70/161 reads (43%) | catalogued as COSV61844019; called by muse, mutect2, varscan2
- KRTAP27-1 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV101239662; called by muse, mutect2, varscan2
- KRTAP5-10 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs908199975, COSV100924118; called by muse, mutect2, varscan2
- L1CAM | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100648822; called by muse, mutect2, varscan2
- LAMB4 | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99222414, COSV99224028; called by muse, mutect2, varscan2
- LAMP1 | c.401A>G p.K134R | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.34); catalogued as rs1249665579, COSV100208429; called by muse, mutect2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/192 reads (21%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LAX1 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100919963; called by muse, varscan2
- LAX1 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100919964; called by muse, varscan2
- LAX1 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | catalogued as COSV100919965; called by muse, mutect2
- LCE1A | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.39); catalogued as rs956132409, COSV100632024; called by muse, mutect2, varscan2
- LDB2 | c.1050C>A p.S350R | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV100452453; called by muse, mutect2, varscan2
- LDB2 | c.613A>T p.R205W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100452456; called by muse, mutect2, varscan2
- LEPR | c.2647T>A p.W883R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756220; called by muse, mutect2, varscan2
- LGALS9B | c.1066A>T p.T356S (on ENST00000423676 / NM_001367292.1; = p.T355S on NM_001042685.2) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV100162855; called by mutect2, varscan2
- LGI2 | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs535857356, COSV101180732; called by muse, mutect2, varscan2
- LHPP | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100919180; called by muse, mutect2, varscan2
- LHX8 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99632887; called by muse, mutect2
- LHX8 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs776961606, COSV53956297; called by muse, mutect2
- LILRA6 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs1460675378, COSV99556895; called by muse, varscan2
- LILRB2 | c.956-1G>T p.X319_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100078920; called by mutect2, varscan2
- LILRB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV54406647; called by muse, mutect2, varscan2
- LIN7A | c.165dup p.V56Sfs*5 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | catalogued as rs1491270675; called by mutect2, pindel
- LIPC | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs138967170; called by muse, mutect2, varscan2
- LIPG | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99724237; called by muse, mutect2, varscan2
- LIPG | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as COSV99724238; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as rs780042765; called by mutect2, varscan2
- LMX1A | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99671500; called by muse, mutect2, varscan2
- LONRF3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100504193; called by muse, mutect2, varscan2
- LPA | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 44/104 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100305902; called by muse, mutect2, varscan2
- LPAR4 | c.826C>A p.R276S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); catalogued as COSV101425066; called by muse, mutect2, varscan2
- LRFN1 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99952568; called by muse, mutect2
- LRP1 | c.11389C>T p.R3797C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54514577; called by mutect2, varscan2
- LRP4 | c.4593G>T p.W1531C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101066123; called by muse, mutect2, varscan2
- LRRC15 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs774632751, COSV61649690; called by muse, mutect2, varscan2
- LRRC37A3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/224 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV100140778; called by muse, mutect2
- LRRC37B | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100495964; called by muse, mutect2, varscan2
- LRRC7 | c.4082T>G p.F1361C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV99224036; called by muse, mutect2, varscan2
- LRRN2 | c.1550C>A p.A517D | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV100912718; called by muse, mutect2, varscan2
- LRRTM4 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV101297409; called by muse, mutect2, varscan2
- LTBP2 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV99999517; called by muse, mutect2, varscan2
- LVRN | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as rs1412233207, COSV100773286, COSV63495941; called by muse, mutect2, varscan2
- LYST | c.10374G>C p.P3458= | Splice Region (SNP) | VAF 29/123 reads (24%) | catalogued as COSV101087878; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100975558; called by muse, mutect2, varscan2
- MAGED1 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV100431343; called by muse, mutect2
- MAGED2 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV54498156, COSV99514343; called by muse, mutect2, varscan2
- MAGI2 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100832120; called by muse, mutect2, varscan2
- MAGI3 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773507498, COSV100287849, COSV56841973; called by muse, mutect2, varscan2
- MAP3K11 | c.662A>G p.Q221R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100482148; called by muse, mutect2, varscan2
- MAP3K13 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99406265; called by muse, mutect2, varscan2
- MAP3K20 | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100168660; called by muse, mutect2, varscan2
- MAP3K9 | c.2587C>T p.P863S (on ENST00000554752 / NM_001284230.1; = p.P877S on NM_033141.4) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV101173426; called by muse, mutect2, varscan2
- MAP4K1 | c.2118G>A p.E706= | Splice Region (SNP) | VAF 9/173 reads (5%) | catalogued as COSV101204113; called by muse, mutect2
- MAP7D2 | c.1626+1G>A p.X542_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV101107105; called by muse, mutect2, varscan2
- MAPK7 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100218751; called by muse, mutect2, varscan2
- MAPKBP1 | c.2582G>T p.G861V (on ENST00000456763 / NM_001128608.2; = p.G855V on NM_014994.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV99528802; called by muse, mutect2, varscan2
- MARCHF6 | c.2506G>C p.G836R | Missense Mutation (SNP) | VAF 61/329 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.395); catalogued as COSV99929274; called by muse, mutect2, varscan2
- MARVELD2 | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100347320; called by muse, mutect2, varscan2
- MATN3 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101337425; called by muse, mutect2, varscan2
- MBTD1 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899067; called by muse, mutect2
- MCAM | c.1751A>T p.K584M | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875350; called by muse, mutect2, varscan2
- MCC | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100201941; called by muse, mutect2, varscan2
- MCRIP2 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99552533; called by muse, mutect2
- MDGA2 | c.1665G>T p.M555I (on ENST00000399232 / NM_001113498.2; = p.M257I on NM_182830.4) | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62087993; called by muse, varscan2
- MDGA2 | c.1617A>C p.K539N (on ENST00000399232 / NM_001113498.2; = p.K241N on NM_182830.4) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100636130, COSV62113389; called by muse, varscan2
- MDH2 | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100242540; called by muse, mutect2, varscan2
- ME3 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768573140, COSV100041965; called by muse, mutect2, varscan2
- MED14 | c.3016C>A p.Q1006K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.039); catalogued as COSV100247258; called by muse, mutect2, varscan2
- MED23 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63432308; called by muse, mutect2, varscan2
- MED29 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs765711223, COSV55394149, COSV99655552; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEMO1 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99703571; called by muse, mutect2, varscan2
- MFSD2A | c.913G>A p.G305S (on ENST00000372809 / NM_001136493.3; = p.G292S on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.85); catalogued as rs201045061, COSV65686178, COSV65686487; called by muse, mutect2, varscan2
- MGA | c.3744del p.E1249Rfs*42 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs1193719928; called by mutect2, pindel, varscan2
- MGAT3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV57865488; called by muse, mutect2, varscan2
- MIEF1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 8/91 reads (9%) | catalogued as rs777642593, COSV100307499; called by muse, mutect2
- MMP1 | c.396T>G p.H132Q | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100187753; called by muse, mutect2, varscan2
- MMP11 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99302997; called by muse, mutect2
- MMP13 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1205986455, COSV99506269; called by muse, mutect2, varscan2
- MOGAT1 | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101490084; called by muse, mutect2
- MORN1 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV101047316; called by muse, mutect2
- MPP2 | c.538C>T p.R180C (on ENST00000461854 / NM_001278372.2; = p.R156C on NM_005374.5) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs948967269, COSV52233913; called by muse, mutect2
- MPPED2 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813075; called by muse, mutect2, varscan2
- MRPL1 | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100213708; called by muse, mutect2, varscan2
- MRPS18A | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779680626, COSV100928663; called by muse, mutect2, varscan2
- MRPS31 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100061963; called by muse, mutect2, varscan2
- MS4A13 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV65446094; called by muse, mutect2, varscan2
- MSN | c.1633C>A p.H545N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100814056; called by muse, mutect2, varscan2
- MTCL1 | c.4242G>T p.E1414D (on ENST00000306329 / NM_001378206.1; = p.E1095D on NM_015210.4) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV100093189; called by muse, mutect2
- MTHFD1L | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944776, COSV66224013; called by muse, mutect2, varscan2
- MTMR11 | c.758A>T p.Q253L (on ENST00000439741 / NM_001145862.2; = p.Q181L on NM_181873.3) | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100808686; called by muse, mutect2, varscan2
- MTUS2 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101462044, COSV70915215; called by muse, mutect2, varscan2
- MUC16 | c.33736G>T p.A11246S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV101197651; called by muse, mutect2, varscan2
- MUC16 | c.24874G>A p.A8292T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.01); catalogued as rs778216388, COSV67443869; called by muse, mutect2, varscan2
- MUC16 | c.21039G>T p.M7013I | Missense Mutation (SNP) | VAF 63/283 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101197655, COSV101199919; called by muse, mutect2, varscan2
- MUC16 | c.9074C>A p.S3025Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101197658; called by muse, mutect2, varscan2
- MUC16 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs547056441, COSV101197659; called by muse, mutect2, varscan2
- MUC17 | c.8995G>T p.V2999L | Missense Mutation (SNP) | VAF 244/519 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100071321, COSV60293586; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPC2 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100731522; called by mutect2, varscan2
- MYCBPAP | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs745717495, COSV60406896; called by muse, mutect2
- MYH3 | c.5650G>T p.E1884* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as COSV56866731; called by muse, mutect2, varscan2
- MYH4 | c.5348T>A p.L1783Q | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV99700207; called by muse, mutect2, varscan2
- MYLK | c.4825G>T p.A1609S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100658407, COSV60615954; called by muse, mutect2, varscan2
- MYLK | c.3122C>T p.A1041V | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100658408; called by muse, mutect2, varscan2
- MYLK | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.109); catalogued as COSV100658409; called by muse, mutect2, varscan2
- MYO15A | c.8818G>T p.V2940L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as COSV99230797; called by muse, mutect2, varscan2
- MYO18A | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV62873532; called by muse, mutect2, varscan2
- MYO18B | c.6098C>G p.A2033G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100122392; called by muse, mutect2, varscan2
- MYO1E | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV55682410, COSV55683846, COSV99894049; called by muse, mutect2, varscan2
- MYO1G | c.478A>T p.S160C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348394; called by muse, mutect2, varscan2
- MYOM1 | c.3292G>T p.V1098L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs747313165, COSV99864979; called by muse, mutect2, varscan2
- NAGLU | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99863920; called by muse, mutect2, varscan2
- NAGPA | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 11/132 reads (8%) | PolyPhen benign (0); catalogued as rs200811972, COSV56569542; called by muse, mutect2
- NAGPA | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | PolyPhen benign (0.437); catalogued as COSV100392784; called by muse, mutect2, varscan2
- NAIF1 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66091398; called by muse, mutect2
- NAPG | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100529603; called by muse, mutect2, varscan2
- NAV1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 19/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961319209, COSV99818060; called by muse, mutect2
- NAV3 | c.1377A>T p.K459N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99886198; called by muse, mutect2
- NBAS | c.4824G>T p.M1608I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99866696; called by muse, mutect2, varscan2
- NBAS | c.3707G>C p.R1236P | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99866697; called by muse, mutect2, varscan2
- NCKAP1 | c.2757G>T p.L919F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100719860; called by muse, mutect2, varscan2
- NCOR1 | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99246627; called by muse, mutect2, varscan2
- NCOR1 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV99246635, COSV99250989; called by muse, mutect2, varscan2
- NDC1 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as COSV99323216; called by muse, mutect2, varscan2
- NDC1 | c.1067-2A>T p.X356_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99323217; called by muse, mutect2, varscan2
- NDC80 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.196); catalogued as COSV99859329; called by muse, mutect2, varscan2
- NEB | c.18638C>A p.S6213* | Nonsense Mutation (SNP) | VAF 55/165 reads (33%) | catalogued as COSV50815303, COSV99413964; called by muse, mutect2, varscan2
- NECAP1 | c.540G>T p.R180S | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100331495; called by muse, mutect2, varscan2
- NEDD4L | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99893136; called by muse, mutect2, varscan2
- NEIL3 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99219893; called by muse, mutect2, varscan2
- NELFB | c.460A>T p.M154L | Missense Mutation (SNP) | VAF 84/129 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100546762; called by muse, mutect2, varscan2
- NEUROD1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99716752; called by muse, mutect2, varscan2
- NFASC | c.592T>C p.Y198H (on ENST00000339876 / NM_001378329.1; = p.Y192H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100362627; called by muse, mutect2, varscan2
- NFASC | c.1110G>C p.W370C (on ENST00000339876 / NM_001378329.1; = p.W381C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362630; called by muse, mutect2, varscan2
- NFXL1 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs371099653, COSV100216786; called by muse, mutect2, varscan2
- NGDN | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV68143087; called by muse, mutect2, varscan2
- NID1 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs371251887, COSV99936884; called by muse, mutect2, varscan2
- NINL | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99624421; called by muse, mutect2, varscan2
- NIPAL3 | c.335-1G>T p.X112_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99135125; called by muse, mutect2, varscan2
- NKX2-2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs145819196; called by muse, mutect2, varscan2
1,172 further variants in this file (722 protein-altering or splice-affecting, 409 silent, 41 other) are not listed here.
